Somatic mutation profile of tumor specimen ALCH-B47C-TTP1-A (aliquot ALCH-B47C-TTP1-A-2-0-D-A80E-36) from ALCHEMIST case ALCH-B47C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.9 years (27,737 days).
Specimen ALCH-B47C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4c7b0cc-3f23-4f62-80d9-42ffae31dffc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B47C-NB1-A (Blood Derived Normal), aliquot ALCH-B47C-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccb6dac4-c822-42b7-9621-5edadeeb8b66

The open-access MAF lists 300 somatic variants for this specimen: 217 protein-altering or splice-affecting, 52 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 52, Intron 13, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 8, RNA 7, 3'UTR 4, 5'UTR 4, Splice Region 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 61/310 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 33/315 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG10B | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58142517; called by muse, mutect2, varscan2
- ALMS1 | c.2297A>G p.Q766R | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.642); catalogued as rs1261459225; called by muse, mutect2
- APEX2 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV58192669; called by muse, mutect2, varscan2
- ATP11C | c.2447C>A p.S816* | Nonsense Mutation (SNP) | VAF 27/303 reads (9%) | catalogued as COSV59562505, COSV59576393; called by muse, mutect2
- BCAS2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 33/356 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV65767657; called by muse, mutect2
- CACNA1F | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781913575, COSV59905728; called by muse, mutect2, varscan2
- CCNA1 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs906871336, COSV104371108; called by muse, mutect2
- CEP170 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100316529; called by mutect2, varscan2
- CETN2 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV64745099; called by muse, mutect2
- COL18A1 | c.1820C>T p.S607L (on ENST00000359759 / NM_130444.3; = p.S372L on NM_030582.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100700475; called by muse, mutect2
- COL22A1 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57345319; called by muse, mutect2
- CSMD3 | c.10456C>A p.P3486T (on ENST00000297405 / NM_001363185.1; = p.P3317T on NM_052900.3) | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs536329289, COSV52345333; called by muse, mutect2, varscan2
- CYP2C9 | c.89del p.P30Lfs*9 | Frame Shift Del (DEL) | VAF 21/208 reads (10%) | catalogued as COSV53252368; called by mutect2, pindel, varscan2
- DYNC2I1 | c.2038G>T p.V680L | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs750577126, COSV68104144; called by muse, mutect2, varscan2
- F8 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28935499, CM890045, CM921006, COSV64277695; called by muse, mutect2, varscan2
- FAM47C | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as rs371381467; called by muse, mutect2, varscan2
- FLG | c.6585C>A p.D2195E | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs779185823, COSV64246978; called by muse, mutect2, varscan2
- GPR107 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1312242243; called by muse, varscan2
- HEPH | c.717G>T p.W239C (on ENST00000343002; = p.W293C on NM_138737.5) | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57960787; called by muse, mutect2, varscan2
- HUNK | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs199599516; called by muse, mutect2, varscan2
- IL18 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV54781735; called by muse, mutect2, varscan2
- KCNT2 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99038382; called by muse, mutect2, varscan2
- KRTAP19-5 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.867); catalogued as COSV61859944; called by muse, mutect2, varscan2
- LAMA4 | c.3116A>T p.K1039M (on ENST00000230538 / NM_001105206.3; = p.K1032M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037883; called by muse, mutect2, varscan2
- LILRA1 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1362649479; called by muse, mutect2
- LRP1B | c.5393C>A p.A1798D | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.205); catalogued as rs757579571; called by muse, mutect2, varscan2
- MYOCD | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99060677; called by muse, varscan2
- NDN | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as COSV59358224; called by muse, mutect2, varscan2
- OR52K2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs370060462; called by muse, mutect2
- OR6Y1 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs758697167; called by muse, mutect2, varscan2
- PCDHA5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.334); catalogued as COSV65349753; called by muse, mutect2
- PCDHB6 | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV99169920; called by muse, mutect2, varscan2
- PIWIL3 | c.1950C>A p.F650L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.374); catalogued as rs1447409313, COSV59996461, COSV59998526; called by muse, mutect2, varscan2
- PLCB2 | c.2105A>G p.Y702C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs201519816; called by muse, mutect2, varscan2
- PLEKHA6 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1388088180; called by muse, mutect2, varscan2
- PRSS55 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV60807869; called by muse, mutect2, varscan2
- PTPRK | c.3708+1G>C p.X1236_splice (on ENST00000368215 / NM_001291984.2; = p.X1237_splice on NM_002844.4) | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as COSV63893791; called by muse, mutect2, varscan2
- PTPRN | c.2300C>A p.A767D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99834235; called by muse, mutect2
- PTPRZ1 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1270502156, COSV101100237; called by muse, mutect2
- RNF214 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1336881275, COSV56118518; called by muse, mutect2, varscan2
- RYR3 | c.3115del p.E1039Kfs*20 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | catalogued as COSV101211924; called by mutect2, pindel, varscan2
- SPANXC | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143011063, COSV62841885; called by muse, mutect2
- SPTBN2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs747019461, COSV59458202; called by muse, mutect2, varscan2
- STAG2 | c.1639-1G>C p.X547_splice | Splice Site (SNP) | VAF 11/76 reads (14%) | catalogued as COSV54354339; called by muse, varscan2
- TMEM132B | c.2762C>A p.A921E | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54755234, COSV54760348; called by muse, mutect2, varscan2
- TRIM51 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99792077, COSV99792862; called by muse, mutect2, varscan2
- U2AF1L4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1385656029; called by muse, mutect2, varscan2
- USP36 | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1442683597; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60155819; called by muse, mutect2, varscan2
- ABCC1 | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACACA | c.113T>G p.M38R | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ACADS | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ADAD1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.1971G>T p.W657C | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFM | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- ANK3 | c.10961T>C p.V3654A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMCX5 | c.1190G>T p.C397F | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARNTL2 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASCC3 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ATP7A | c.2348C>G p.T783R | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GNT7 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); called by muse, mutect2
- BDP1 | c.1357G>T p.V453F | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2
- C2orf72 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- C4orf54 | c.5354C>A p.T1785N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- C7 | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNA1H | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNA2D4 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN6 | c.517T>A p.C173S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); called by muse, mutect2
- CBARP | c.2034C>A p.C678* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- CD163 | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP92 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CHD7 | c.8462C>T p.S2821L | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- CHD9 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- CHPF | c.1589C>G p.A530G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CLIP1 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- CLIP2 | c.2989C>A p.L997M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLSTN2 | c.1849A>G p.S617G | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by mutect2, varscan2
- COL11A1 | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- COL11A2 | c.1438C>T p.Q480* (on ENST00000341947 / NM_080680.3; = p.Q373* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- CSMD3 | c.8197G>T p.G2733C | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.7033C>A p.Q2345K (on ENST00000297405 / NM_001363185.1; = p.Q2241K on NM_052900.3) | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- DCAF4L2 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DENND1B | c.2162G>C p.R721P | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DHX35 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DISP3 | c.2861del p.P954Lfs*39 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by pindel, varscan2
- DLGAP1 | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DPP6 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DRD2 | c.502T>A p.C168S | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- DRP2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTHD1 | c.272C>A p.A91E (on ENST00000456874; = p.A216E on NM_001170700.3) | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.2); called by muse, mutect2
- DYNC2H1 | c.8353G>T p.A2785S | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DYNC2LI1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB8 | c.3210G>A p.M1070I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by mutect2, varscan2
- ELF3 | c.1070del p.N357Tfs*90 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, pindel, varscan2
- F8 | c.4444G>C p.G1482R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- FAM171B | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | called by muse, varscan2
- FAM83H | c.3392G>T p.R1131L | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- FAT3 | c.13051G>T p.A4351S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- FOXO4 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- GALE | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, varscan2
- GALE | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GALNT17 | c.1370T>A p.M457K | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- GCM1 | c.821A>C p.Y274S | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- GPX5 | c.88-1G>A p.X30_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- GRK5 | c.264A>G p.A88= | Splice Region (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- HS6ST2 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 30/301 reads (10%) | called by muse, mutect2
- IGF2BP1 | c.151A>T p.M51L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- IGHD | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- IGHM | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- IGLV1-47 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); called by muse, mutect2
- IL1RAPL1 | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INAVA | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INTS9 | c.593del p.G198Dfs*14 | Frame Shift Del (DEL) | VAF 18/145 reads (12%) | called by mutect2, pindel, varscan2
- IQCE | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ITGA4 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ITGA8 | c.803-1G>T p.X268_splice | Splice Site (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- ITIH6 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- ITM2B | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ITPRIPL1 | c.308G>A p.G103E (on ENST00000439118 / NM_001008949.3; = p.G111E on NM_178495.6) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- KCNE5 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KCNMA1 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KDM1A | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KIDINS220 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF16B | c.1067A>T p.K356I | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF21B | c.2920G>T p.G974W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KLF3 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KNTC1 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- LAMP2 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LHX9 | c.108_109dup p.M37Rfs*58 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- LRP1B | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPKAPK2 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF8 | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MED12 | c.1950A>T p.E650D | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MGAM2 | c.4731G>T p.M1577I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- MUC17 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MUC17 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MUC2 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.17); called by muse, mutect2, varscan2
- MYLK3 | c.777G>T p.R259S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NARS2 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); called by muse, mutect2
- NBPF9 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 25/556 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); called by muse, mutect2
- NEB | c.9915del p.W3305Cfs*87 | Frame Shift Del (DEL) | VAF 22/169 reads (13%) | called by mutect2, pindel, varscan2
- NFKBIE | c.691G>T p.D231Y (on ENST00000275015; = p.D92Y on NM_004556.3) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- NKD2 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NLGN4X | c.2073A>T p.L691F | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NLGN4X | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAS4 | c.871T>A p.W291R | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NRK | c.992C>A p.T331N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.946); called by muse, mutect2
- NSFL1C | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NSFL1C | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OBSCN | c.16332G>C p.Q5444H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- OLFM4 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR4K17 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OR4Q3 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- OR5B17 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2
- OR5T3 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- OR7G3 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCDHGB5 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDCL3 | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PGK2 | c.1172A>T p.H391L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PIEZO2 | c.5396T>C p.V1799A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CG | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2
- PLEK2 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLPP6 | c.610del p.S204Rfs*17 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | called by mutect2, pindel
- POLR2C | c.137-2del p.X46_splice | Splice Site (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- PRTG | c.2907G>T p.L969F | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PTPRN2 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by mutect2, varscan2
- PTPRO | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PTPRQ | c.2860G>T p.D954Y (on ENST00000616559; = p.D912Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RAB39A | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- RASGRF1 | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- RBM5 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- REM1 | c.832C>G p.R278G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RESP18 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- RFX5 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHBG | c.528G>T p.V176= | Splice Region (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- RP1L1 | c.3704C>A p.S1235Y | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- RPS6KA6 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- RRN3 | c.1319A>T p.Q440L | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.1891C>A p.L631M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD9 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- SAT1 | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SEC16B | c.1565G>T p.W522L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- SEC31A | c.3439A>T p.S1147C (on ENST00000355196 / NM_001318120.1; = p.S1108C on NM_016211.4) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); called by muse, mutect2
- SETD5 | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SLAMF6 | c.566G>T p.S189I | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SLC6A16 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- SLC6A18 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SMARCA1 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SOX21 | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STAG2 | c.2749A>T p.K917* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- SV2A | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, varscan2
- SYMPK | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- TAOK1 | c.1321A>T p.I441L | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TKTL2 | c.1100T>A p.I367N | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM219 | c.586-2A>T p.X196_splice | Splice Site (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2
- TNMD | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TPP2 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- TRIM37 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TRPA1 | c.2132+1G>C p.X711_splice | Splice Site (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- TRPM6 | c.3660T>A p.D1220E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPYL1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2
- TTN | c.15932G>A p.S5311N (on ENST00000591111; = p.S4384N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | PolyPhen benign (0.049); called by mutect2, varscan2
- UGGT2 | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- USH2A | c.1676A>G p.K559R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP34 | c.4265del p.G1422Dfs*33 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel, varscan2
- USP8 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.366); called by muse, mutect2
- VCAN | c.6770G>C p.G2257A | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY4 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- ZAN | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- ZDBF2 | c.1862G>C p.S621T | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2
- ZFC3H1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2
- ZMAT1 | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2
- ZNF208 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF800 | c.227G>C p.S76T | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF841 | c.1196G>A p.C399Y (on ENST00000426391 / NM_001369830.1; = p.C515Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS2 | c.2607C>T p.P869= | Silent (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- BPIFB1 | c.744G>C p.L248= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99487444; called by muse, mutect2, varscan2
- C4orf54 | c.5355C>A p.T1785= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- CLINT1 | c.426C>T p.D142= | Silent (SNP) | VAF 58/235 reads (25%) | catalogued as rs908128183, COSV99753279; called by muse, mutect2, varscan2
- CNTNAP5 | c.2691C>T p.T897= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV101443793; called by muse, mutect2
- CNTNAP5 | c.3828G>A p.E1276= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as rs1363564677; called by muse, mutect2, varscan2
- COL3A1 | c.3171A>G p.P1057= | Silent (SNP) | VAF 40/267 reads (15%) | called by muse, mutect2, varscan2
- COL5A2 | c.3885G>C p.T1295= | Silent (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- CSMD2 | c.882C>T p.H294= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2
- CTTNBP2 | c.1017A>G p.A339= | Silent (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.300C>A p.G100= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- DNAH14 | c.5085A>T p.T1695= (on ENST00000445597; = p.T2100= on NM_001367479.1) | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.5526C>T p.S1842= | Silent (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- EPHA10 | c.333C>T p.D111= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- FAM43B | c.177G>C p.R59= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- FBRS | c.771G>T p.R257= (on ENST00000287468; = p.R777= on NM_001105079.3) | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- FRMD7 | c.939G>A p.G313= | Silent (SNP) | VAF 41/387 reads (11%) | catalogued as rs1307353318; called by muse, mutect2, varscan2
- GAB3 | c.1096C>A p.R366= | Silent (SNP) | VAF 30/256 reads (12%) | called by muse, mutect2, varscan2
- GPATCH1 | c.642T>C p.N214= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- GPR162 | c.1125A>T p.T375= (on ENST00000311268 / NM_019858.2; = p.T91= on NM_014449.2) | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1560A>T p.G520= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- INAVA | c.1068G>T p.G356= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ITGA1 | c.2673C>T p.P891= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- IZUMO3 | c.117G>A p.L39= | Silent (SNP) | VAF 65/354 reads (18%) | called by muse, mutect2, varscan2
- KCNMB4 | c.132G>A p.L44= | Silent (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
- KRT38 | c.660C>A p.A220= | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- KRT83 | c.411G>A p.K137= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs774847841; called by muse, mutect2
- LAS1L | c.777C>A p.A259= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- LCE2A | c.6C>T p.S2= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV64227165; called by muse, mutect2
- LRP1B | c.12069A>C p.T4023= | Silent (SNP) | VAF 35/298 reads (12%) | called by muse, mutect2, varscan2
- MMP19 | c.750G>T p.G250= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100491203; called by muse, mutect2
- OR1S2 | c.123T>C p.F41= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- OR2T4 | c.195G>A p.V65= | Silent (SNP) | VAF 64/440 reads (15%) | called by muse, mutect2, varscan2
- OR5B17 | c.246G>T p.G82= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- OR5D14 | c.237C>A p.V79= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- OR7C1 | c.228G>T p.T76= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- PDGFRA | c.3126G>A p.S1042= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as rs141904599, COSV57271253; called by muse, mutect2
- POTEC | c.429C>A p.L143= | Silent (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- PTPRS | c.4188G>A p.E1396= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- RFPL4A | c.756A>G p.P252= | Silent (SNP) | VAF 66/1017 reads (6%) | catalogued as rs762589151; called by muse, mutect2
- RFPL4AL1 | c.756A>G p.P252= | Silent (SNP) | VAF 27/239 reads (11%) | catalogued as rs1270983991; called by muse, mutect2, varscan2
- ROS1 | c.2604G>T p.G868= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- SCN2A | c.3940C>T p.L1314= | Silent (SNP) | VAF 42/272 reads (15%) | called by muse, mutect2, varscan2
- SLITRK1 | c.681G>T p.L227= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- SNAP91 | c.2628G>T p.T876= | Silent (SNP) | VAF 18/229 reads (8%) | catalogued as rs770091414; called by muse, mutect2
- SPATA31E1 | c.3189T>C p.D1063= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV57793564; called by muse, mutect2, varscan2
- SPATC1L | c.852C>A p.I284= (on ENST00000291672 / NM_001142854.2; = p.I130= on NM_032261.5) | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- STRA8 | c.498C>T p.I166= (on ENST00000275764; = p.I144= on NM_182489.2) | Silent (SNP) | VAF 48/302 reads (16%) | catalogued as COSV51962977; called by muse, mutect2, varscan2
- TENT5D | c.1086T>C p.P362= | Silent (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- TRIP11 | c.2211C>T p.N737= | Silent (SNP) | VAF 88/546 reads (16%) | called by muse, mutect2, varscan2
- XIAP | c.654A>T p.S218= | Silent (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- ZNF90 | c.501T>C p.D167= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs782373443; called by muse, mutect2, varscan2
- AC011487.1 | n.311T>A | RNA (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2, varscan2
- AREL1 | c.-473G>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- BCOR | c.-16C>A | 5'UTR (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700857 C>A | 3'Flank (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- CCDC144B | n.238C>T | RNA (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- COLEC11 | c.*247G>T | 3'UTR (SNP) | VAF 45/316 reads (14%) | called by muse, mutect2, varscan2
- CREG1 | c.*30A>G | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- DCHS2 | n.2394C>A | RNA (SNP) | VAF 20/63 reads (32%) | catalogued as rs770120703; called by muse, mutect2, varscan2
- FUNDC2P2 | n.406C>T | RNA (SNP) | VAF 73/507 reads (14%) | called by muse, mutect2, varscan2
- GALE | c.795+40G>A | Intron (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- ITIH5 | c.2032+758A>T | Intron (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- LINC01100 | n.364C>G | RNA (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- MROH8 | c.370+2427A>T | Intron (SNP) | VAF 22/168 reads (13%) | called by muse, varscan2
- MYLK3 | c.2115-812G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- NR0B1 | c.1169-949A>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- NRXN1 | c.3365-109755C>G | Intron (SNP) | VAF 35/265 reads (13%) | called by muse, varscan2
- OXCT1 | c.1173-50G>T | Intron (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- PTMS | c.-139C>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as rs1565478831; called by muse, varscan2
- PTPRT | c.2983-782A>T | Intron (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791035 del G | 5'Flank (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel, varscan2
- SLC25A42 | c.213+36G>T | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- SLC25A5 | chrX:119468262 C>G | 5'Flank (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2
- SLC9B1P1 | n.611C>A | RNA (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- SMARCA4 | c.1593+212G>T | Intron (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.2001-540C>T | Intron (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1046A>G | Intron (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2
- TAZ | c.*7C>A | 3'UTR (SNP) | VAF 35/301 reads (12%) | called by muse, mutect2, varscan2
- TG | c.7239+29122G>A | Intron (SNP) | VAF 14/158 reads (9%) | catalogued as rs532909631; called by muse, mutect2
- UBE2DNL | n.253G>A | RNA (SNP) | VAF 3/21 reads (14%) | catalogued as rs1374347389; called by muse, mutect2
- XIAP | c.*4321C>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | catalogued as rs1190498224; called by muse, mutect2
- ZNF208 | c.-14C>A | 5'UTR (SNP) | VAF 11/78 reads (14%) | catalogued as rs878985435; called by muse, mutect2, varscan2
